Gene-level copy-number profile of specimen HCM-CSHL-0078-C25-85Q from HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-85Q: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 87a8315a-69bc-47bb-be5c-6a62bbf6c3df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0078-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/2abe0bb4-b7f8-4b0c-8720-e8199f60156b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 20; copy number 2: 11,951; copy number 3: 32,849; copy number 4: 9,036; copy number 5: 3,975; copy number 6: 613; copy number 7: 133; copy number 8: 91; copy number 9: 102; copy number 10: 89; copy number 15: 24.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 439 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,670,852–145,824,095, 3 genes, copy number 9 (within-gene range 5–9): PDZK1, CD160, RNF115.
- chr1:147,541,501–149,321,732, 66 genes, copy number 7 (broad region; genes not listed).
- chr1:150,487,364–152,078,211, 99 genes, copy number 9 (broad region; genes not listed).
- chr1:154,312,462–154,870,281, 18 genes, copy number 7: AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1, SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, CHRNB2, AL592078.1, ADAR, KCNN3.
- chr2:131,361,111–131,410,050, 16 genes, copy number 8: RAB6D, AC073869.3, MTCYBP10, MTND6P10, MTND5P23, MTND4P21, AC073869.4, MTCO3P18, MTATP6P4, MTCO2P18, MTCO1P18, MTND2P18, MTND1P26, MED15P3, AC073869.2, LINC01120.
- chr2:131,464,900–132,406,858, 36 genes, copy number 8: MZT2A, TUBA3D, MIR4784, SMPD4BP, CCDC74A, MED15P4, POTEKP, RNU6-617P, LINC01087, GRAMD4P8, C2orf27A, NBEAP2, TOMM40P4, CDRT15P4, CDRT15P3, AC103564.3, AC103564.1, AC103564.2, AJ239322.2, AJ239322.1, LINC01945, AC093787.1, AC098826.3, AC098826.1, AC098826.2, ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B, CDC27P1, AC097532.1, ZNF806, AC097532.2, AC097532.3, FAM201B, RNU6-175P.
- chr6:32,439,878–32,838,822, 18 genes, copy number 7: HLA-DRA, HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1, AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2.
- chr6:32,948,613–33,329,286, 37 genes, copy number 10–15 (within-gene range 5–15): HLA-DMA, BRD2, AL645941.1, AL645941.3, HLA-DOA, HLA-DPA1, HLA-DPB1, RPL32P1, HLA-DPA2, COL11A2P1, HLA-DPB2, HLA-DPA3, HCG24, COL11A2, RXRB, RNY4P10, SLC39A7, HSD17B8, MIR219A1, RING1, ZNF70P1, HTATSF1P1, AL645940.1, HCG25, VPS52, RPS18, B3GALT4, WDR46, MIR6873, PFDN6, MIR6834, RGL2, TAPBP, ZBTB22, DAXX, SMIM40, SMIM40.
- chr6:41,149,342–41,790,141, 30 genes, copy number 7–10 (within-gene range 6–10): TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6.
- chr6:50,514,035–53,924,125, 72 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr9:65,189,995–65,230,861, 3 genes, copy number 8: BMS1P12, AL512605.1, AL512605.2.
- chr9:66,082,350–66,085,031, 2 genes, copy number 7: SNX18P4, AL513478.1.
- chr16:33,907,419–33,937,167, 1 gene, copy number 7: ARHGAP23P1.
- chr20:2,075,555–3,094,509, 36 genes, copy number 8: RPL7P2, STK35, AL359916.1, AL121899.4, AL121899.1, AL121899.2, TGM3, TGM6, Y_RNA, SNRPB, AL049650.1, ZNF343, TMC2, NOP56, MIR1292, SNORD110, SNORA51, SNORD86, SNORD56, SNORD57, IDH3B, AL049712.1, EBF4, RPL19P1, CPXM1, AL035460.1, C20orf141, TMEM239, PCED1A, VPS16, PTPRA, GNRH2, MRPS26, OXT, AVP, RN7SL555P.
- chr22:21,370,064–21,379,701, 2 genes, copy number 7: AP000552.1, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
